Surgical pathology report (de-identified scan), TCGA case TCGA-29-2414, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2414-02A (Recurrent Tumor).

Surg Path

CLINICAL HISTORY:

History of Stage IV suboptimal debulking of ovarian carcinoma - thin needle aspirate showed metastatic CA.

GROSS EXAMINATION:

A. "Right groin node", received fresh. A three-dimensional portion of fibroadipose tissue, 3.8 x 2.7 x 2.0 cm, is inked and sectioned to reveal a 2.5 x 1.5 x 1.3 cm friable pink/tan nodule. Representative submitted as A1. Also received is a 2.0 x 1.2 x 0.6 cm portion of adipose tissue containing a 0.6 x 0.5 x 0.4 cm lymph node candidate which is submitted in toto in A2.

DIAGNOSIS:

A. "RIGHT GROIN NODULE" (BIOPSY):

ONE OF TWO LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA CONSISTENT WITH OVARIAN PRIMARY (1/2).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

1CΔ-0-3 Mcurrence

*Carcinoma, NOS, metastatic 8010/6
Site: lymph node, groin C77.4*

ADDENDUM 1:

PROLIFERATION INDEX IMAGE ANALYSIS

A tissue block was sent to the Image Cytometry Laboratory for assay of proliferation index (block A1). The PROLIFERATION INDEX is judged to be HIGH with an estimated positive nuclear area percentage of 72%. Please refer to for a complete report.

*hw
2/12/15*

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 04efb39c-3b5d-412b-9c02-2814a94c1466 (TCGA-29-2414.1A4882EA-818E-4A23-8584-2881D0DE8406.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).